Gene-level copy-number profile of tumor specimen TCGA-CN-4722-01A from TCGA case TCGA-CN-4722, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 61.1 years (22,299 days).
Specimen TCGA-CN-4722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.dfbd9b87-a9d1-41c4-8765-7da00b5c9ca9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4722-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64cfcec9-b9ba-490b-9d2a-8ec9600230b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 184; copy number 1: 2,466; copy number 2: 52,246; copy number 3: 4,918.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CN-4722-01): tumor purity 0.32, ploidy 2.08, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 182 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:60,914,407–68,644,442, 176 genes (within-gene range 0–2) (broad region; genes not listed).
- chr10:4,962,436–5,018,031, 4 genes (within-gene range 0–2): U8, AKR1C1, AKR1C2, AL391427.1.
- chr11:71,568,680–71,568,934, 1 gene: AP000867.1.
- chr11:71,579,728–71,579,848, 1 gene: KRTAP5-14P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
